Somatic mutation profile of tumor specimen ALCH-B2RS-TTP1-A (aliquot ALCH-B2RS-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2RS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.3 years (24,592 days).
Specimen ALCH-B2RS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9dcfa47-47bd-447b-ba31-6c375eec0ea5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2RS-NB1-A (Blood Derived Normal), aliquot ALCH-B2RS-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ebfa72e-b1fa-41c9-af47-cdfd643b2435

The open-access MAF lists 32 somatic variants for this specimen: 22 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 8, Splice Region 4, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 85/1585 reads (5%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs11554273, COSV55670339, COSV55670675, COSV55677163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 66/646 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- B4GALNT4 | c.2572G>A p.V858I | Missense Mutation (SNP) | VAF 23/377 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.091); catalogued as COSV57323588; called by muse, mutect2
- CDH12 | c.1272G>T p.W424C | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV66444705; called by muse, mutect2
- EVC | c.1101C>T p.D367= | Splice Region (SNP) | VAF 48/934 reads (5%) | catalogued as rs186537549; ClinVar: likely benign; called by muse, mutect2
- GRIPAP1 | c.2437A>G p.M813V | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.552); catalogued as COSV54416275; called by muse, mutect2
- KDM2B | c.2326C>T p.R776C | Missense Mutation (SNP) | VAF 30/592 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs374773877; called by muse, mutect2
- LOXHD1 | c.4127T>A p.I1376N | Missense Mutation (SNP) | VAF 28/543 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1420571365, COSV100192780; called by muse, mutect2
- NELL2 | c.2141C>A p.T714N | Missense Mutation (SNP) | VAF 27/267 reads (10%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.575); catalogued as rs1271739971; called by muse, mutect2, varscan2
- RASGRP3 | c.1638A>T p.R546S (on ENST00000402538 / NM_001349975.2; = p.R545S on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/752 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.392); catalogued as rs1436639104; called by muse, mutect2
- SAFB | c.1149-4C>G | Splice Region (SNP) | VAF 27/323 reads (8%) | catalogued as rs1230610733; called by muse, mutect2
- UBA7 | c.2995G>A p.D999N | Missense Mutation (SNP) | VAF 30/673 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs1041984929; called by muse, mutect2
- ASCL1 | c.396G>C p.K132N | Missense Mutation (SNP) | VAF 32/574 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- CYHR1 | c.382G>T p.V128L | Missense Mutation (SNP) | VAF 40/733 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2
- DIABLO | c.407C>T p.A136V (on ENST00000443649 / NM_001278303.1; = p.A209V on NM_019887.6) | Missense Mutation (SNP) | VAF 76/747 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); called by muse, mutect2
- DUSP13 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 54/976 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- FAM9C | c.183G>T p.G61= | Splice Region (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2
- FGD1 | c.2077C>A p.Q693K | Missense Mutation (SNP) | VAF 14/320 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.057); called by muse, mutect2
- GLRB | c.906T>A p.G302= | Splice Region (SNP) | VAF 22/572 reads (4%) | called by muse, mutect2
- LRCH2 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 40/505 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2
- MAN2A2 | c.1487A>G p.Y496C | Missense Mutation (SNP) | VAF 24/531 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF473 | c.1976C>T p.A659V | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.019); called by muse, mutect2
- ASAH2 | c.973C>T p.L325= | Silent (SNP) | VAF 44/677 reads (6%) | called by muse, mutect2
- CRYBB1 | c.555C>T p.S185= | Silent (SNP) | VAF 45/952 reads (5%) | catalogued as rs186415130, COSV53233990; called by muse, mutect2
- DNAJC22 | c.309C>A p.V103= | Silent (SNP) | VAF 54/738 reads (7%) | called by muse, mutect2
- DOK6 | c.243A>C p.A81= | Silent (SNP) | VAF 26/402 reads (6%) | called by muse, mutect2
- HAO1 | c.513G>A p.V171= | Silent (SNP) | VAF 16/262 reads (6%) | called by muse, mutect2
- HTATSF1 | c.2091C>T p.F697= | Silent (SNP) | VAF 22/350 reads (6%) | catalogued as rs774018492, COSV54478271; called by muse, mutect2
- LRRC14B | c.804C>T p.L268= | Silent (SNP) | VAF 10/160 reads (6%) | catalogued as rs1275050500, COSV104368925, COSV52052649; called by muse, mutect2
- WRN | c.522C>T p.T174= | Silent (SNP) | VAF 18/448 reads (4%) | called by muse, mutect2
- DEPDC5 | c.3030+3849C>T | Intron (SNP) | VAF 16/458 reads (3%) | catalogued as rs1414864434; called by muse, mutect2
- LINC01135 | n.256A>G | RNA (SNP) | VAF 21/380 reads (6%) | called by muse, mutect2
